Gene-level copy-number profile of tumor specimen ALCH-B1KI-TTP1-A from ALCHEMIST case ALCH-B1KI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.7 years (24,367 days).
Specimen ALCH-B1KI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d418173d-9ced-4cdd-b7f2-b45566980f62.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1KI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/8417c12d-220a-4638-b10f-b2befad7130c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 125; copy number 1: 15,858; copy number 2: 38,931; copy number 3: 2,109; copy number 4: 606; copy number 5: 3; copy number 6: 150; copy number 7: 558; copy number 8: 17; copy number 15: 4; copy number 16: 3; copy number 18: 7; copy number 25: 32.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,683,360–140,992,659, 3 genes (within-gene range 0–1): COPRSP1, LRRC57P1, Y_RNA.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr6:29,887,294–29,908,645, 5 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1.
- chr9:20,331,446–26,118,408, 86 genes (broad region; genes not listed).
- chr9:115,119,539–115,138,409, 1 gene: AL162425.1.
- chr11:1,223,066–1,262,172, 3 genes (within-gene range 0–2): MUC5B, MUC5B-AS1, MIR6744.
- chr16:10,718,633–10,725,296, 8 genes: MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24.
- chr17:7,661,779–7,687,538, 1 gene (within-gene range 0–1): TP53.
- chr19:42,752,686–43,171,515, 11 genes (within-gene range 0–1): PSG8, CEACAMP6, PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 774 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:155,870,650–157,677,749, 37 genes, copy number 6: GMPS, AC104472.5, SETP14, VN2R1P, KCNAB1, ALG1L15P, MRE11P1, AC091607.2, AC091607.1, KCNAB1-AS2, KCNAB1-AS1, AC084036.1, SSR3, TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4, LEKR1, KLF3P2, AC117392.1, RN7SKP177, LINC00880, LINC02029, LINC00881, CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146, AC092944.1, AC092944.2, AC092944.3, VEPH1, PTX3, SLC66A1L, AC084212.1.
- chr3:158,545,189–198,123,232, 688 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:37,067,441–38,383,461, 46 genes, copy number 15–25: AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2.
- chr8:127,289,817–127,482,139, 1 gene, copy number 5 (within-gene range 2–5): CASC8.
- chr8:127,322,183–127,420,066, 2 genes, copy number 5: POU5F1B, CCAT2.

Autosomal genes at a single copy (total copy number 1): 13,744. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
